Somatic mutation profile of tumor specimen TCGA-AN-A0G0-01A (aliquot TCGA-AN-A0G0-01A-11W-A050-09) from TCGA case TCGA-AN-A0G0, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.1 years (20,504 days).
Specimen TCGA-AN-A0G0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f10bd6e-133c-4c48-9d60-853c9e9c3363.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0G0-10A (Blood Derived Normal), aliquot TCGA-AN-A0G0-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c0ccace-ab21-43a6-a526-bf471de842ea

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 5, Nonsense Mutation 4, Frame Shift Ins 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 41/61 reads (67%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.79); PolyPhen benign (0.066); catalogued as rs756151860, COSV55113792; called by muse, mutect2, varscan2
- ABCA4 | c.6427A>T p.M2143L | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as rs1286076948, COSV64671749; called by muse, mutect2, varscan2
- ACVR1B | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 39/88 reads (44%) | catalogued as COSV57775510; called by muse, mutect2, varscan2
- AFF2 | c.2371C>G p.P791A | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV53980433; called by muse, mutect2, varscan2
- ALG10B | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV58142605; called by muse, mutect2, varscan2
- ARMH4 | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 73/92 reads (79%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as rs772692558, COSV50762429; called by muse, mutect2, varscan2
- BRWD1 | c.6837dup p.L2280Ifs*6 | Frame Shift Ins (INS) | VAF 13/37 reads (35%) | catalogued as rs1568841963; called by mutect2, pindel, varscan2
- C10orf71 | c.691G>C p.G231R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs183879740, COSV100110414, COSV60505553; called by muse, mutect2
- CAMK2D | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV56427263; called by muse, mutect2, varscan2
- CHD7 | c.4611G>C p.K1537N | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV71107709; called by muse, mutect2
- GRM3 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.919); catalogued as COSV64468590; called by muse, mutect2, varscan2
- LAMA2 | c.7058G>A p.R2353H | Missense Mutation (SNP) | VAF 57/243 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs548483084, COSV70341509; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NID1 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51616252, COSV51625470; called by muse, mutect2, varscan2
- NTSR2 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.515); catalogued as rs574844067, COSV60990662; called by muse, mutect2, varscan2
- NUP153 | c.3157A>T p.I1053L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV50446864; called by muse, mutect2, varscan2
- PGD | c.868T>G p.L290V | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV54620565; called by muse, mutect2, varscan2
- PHACTR1 | c.1736G>T p.R579L | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV100276226, COSV60661364; called by muse, mutect2, varscan2
- PHLDA1 | c.702C>A p.F234L | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV56996888; called by muse, mutect2, varscan2
- SNRPN | c.295G>T p.G99* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV57594685; called by muse, mutect2, varscan2
- SUPT5H | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63238648; called by muse, mutect2, varscan2
- TGFBR2 | c.1563G>A p.W521* | Nonsense Mutation (SNP) | VAF 88/141 reads (62%) | catalogued as rs1553631968, COSV55445356, COSV55459591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TOR1AIP1 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.212); catalogued as COSV54868698; called by muse, mutect2, varscan2
- USP2 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369164717; called by muse, mutect2, varscan2
- USP5 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs782807103, COSV57531057; called by muse, mutect2, varscan2
- USP9X | c.6172C>G p.H2058D | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV61066923; called by muse, mutect2, varscan2
- H2AC20 | c.346_349dup p.L117Sfs*28 | Frame Shift Ins (INS) | VAF 19/139 reads (14%) | called by mutect2, pindel, varscan2
- AOAH | c.315T>C p.D105= | Silent (SNP) | VAF 151/425 reads (36%) | catalogued as COSV51737078; called by muse, mutect2, varscan2
- COL14A1 | c.1359C>T p.D453= | Silent (SNP) | VAF 59/127 reads (46%) | catalogued as rs770905335, COSV52849200; called by muse, mutect2, varscan2
- FGF23 | c.526C>A p.R176= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as CM095144, COSV52975375, COSV52975708; called by muse, mutect2, varscan2
- GPR39 | c.543G>T p.V181= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV61421780, COSV61423632; called by muse, mutect2, varscan2
- MCAM | c.1672C>A p.R558= | Silent (SNP) | VAF 46/83 reads (55%) | catalogued as COSV50631476; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95663515 C>G | 3'Flank (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2, varscan2
- STARD7-AS1 | n.1552_1554del | RNA (DEL) | VAF 40/89 reads (45%) | called by mutect2, pindel, varscan2
